Somatic mutation profile of tumor specimen ALCH-B2M0-TTP1-A (aliquot ALCH-B2M0-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2M0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 80.3 years (29,314 days).
Specimen ALCH-B2M0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a504b558-35b6-4de2-8707-e8228875b96d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2M0-NB1-A (Blood Derived Normal), aliquot ALCH-B2M0-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e85de3cf-996f-40b4-9628-13ed5ef94b3a

The open-access MAF lists 166 somatic variants for this specimen: 121 protein-altering or splice-affecting, 29 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 29, Nonsense Mutation 13, Intron 6, RNA 5, Splice Site 4, 3'UTR 4, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.5713G>T p.E1905* | Nonsense Mutation (SNP) | VAF 17/223 reads (8%) | catalogued as rs1557291003; ClinVar: pathogenic; called by muse, mutect2
- ADCY5 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | catalogued as rs1553720819; called by muse, mutect2
- ADGRB3 | c.3802C>A p.P1268T | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53259911; called by muse, mutect2
- ADGRB3 | c.3803C>A p.P1268Q | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53254779; called by muse, mutect2
- AKAP6 | c.1663G>C p.E555Q | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.107); catalogued as COSV55216030, COSV55235608; called by muse, mutect2
- ANKRD62 | c.2381G>C p.R794P | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs561988829; called by muse, mutect2, varscan2
- CCDC168 | c.6799G>A p.D2267N | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.801); catalogued as COSV70555534; called by muse, mutect2
- CDYL2 | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1366494845; called by muse, mutect2
- CEMIP2 | c.2560G>T p.D854Y | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV65484448; called by muse, mutect2
- CENPJ | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs985888847; called by muse, mutect2
- CFAP77 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV57505887; called by muse, mutect2
- CLOCK | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866960017; called by muse, mutect2, varscan2
- CMTR2 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100579351; called by muse, mutect2
- CROCC2 | c.1034T>A p.L345Q | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs1330941859; called by muse, mutect2
- DENND1B | c.561+1G>T p.X187_splice | Splice Site (SNP) | VAF 11/202 reads (5%) | catalogued as COSV99344496; called by muse, mutect2
- DROSHA | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as COSV60779736, COSV99078269; called by muse, mutect2
- FSIP2 | c.4177C>A p.Q1393K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs992184658; called by muse, mutect2
- GABRA2 | c.799C>T p.L267F | Missense Mutation (SNP) | VAF 11/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734850; called by muse, mutect2
- GLIPR1L2 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.505); catalogued as COSV100248477, COSV100248491; called by muse, mutect2
- GPR179 | c.3973G>A p.E1325K (on ENST00000621958; = p.E1324K on NM_001004334.4) | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as rs201039021; ClinVar: uncertain significance; called by muse, mutect2
- HMCN1 | c.14510G>T p.R4837L | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV54888710; called by muse, mutect2
- KNSTRN | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1451804009; called by muse, mutect2
- KRTAP9-2 | c.366C>A p.Y122* | Nonsense Mutation (SNP) | VAF 38/656 reads (6%) | catalogued as rs1568051125; called by muse, mutect2
- KRTAP9-9 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 15/305 reads (5%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.631); catalogued as COSV67454076, COSV67454181; called by muse, mutect2
- LGALS9B | c.88C>G p.Q30E | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV60864419; called by muse, mutect2
- NBEA | c.4243-1G>T p.X1415_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | catalogued as COSV59781094; called by muse, mutect2
- NMRAL1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 28/386 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs751342170; called by muse, mutect2
- OR6P1 | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 14/219 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58110283; called by muse, mutect2
- OTC | c.620G>C p.S207T | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as CM062949; called by muse, mutect2
- PCDHB14 | c.2284A>T p.N762Y | Missense Mutation (SNP) | VAF 28/371 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV53387636; called by muse, mutect2
- PTPRF | c.2584G>A p.E862K | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as rs536681179, COSV63444732; called by muse, mutect2
- RAB3GAP2 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 24/279 reads (9%) | catalogued as COSV52967141; called by muse, mutect2
- RNASE3 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58959091; called by muse, mutect2
- RP1L1 | c.3848A>T p.Q1283L | Missense Mutation (SNP) | VAF 41/873 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1331825229; called by muse, mutect2
- SCAF1 | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); catalogued as COSV62182170; called by muse, mutect2
- SIPA1 | c.2924C>A p.S975* | Nonsense Mutation (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100425750; called by muse, mutect2
- SLC16A11 | c.191C>T p.P64L (on ENST00000308009; = p.P40L on NM_153357.3) | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.621); catalogued as rs1567734943, COSV100338750; called by muse, mutect2
- TMC4 | c.1517G>A p.R506K (on ENST00000617472 / NM_001145303.3; = p.R500K on NM_144686.4) | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV55828834; called by muse, mutect2
- TOR1AIP1 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.182); catalogued as COSV99621680; called by muse, mutect2
- UGT1A8 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990068; called by muse, mutect2
- VPS54 | c.2254A>G p.I752V | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.041); catalogued as rs1361014084, COSV55439475; called by muse, mutect2
- ZNF728 | c.599C>G p.S200C | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.896); catalogued as COSV74099067; called by muse, mutect2
- ABCG4 | c.1161G>T p.R387S | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABCG4 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACE | c.3621G>T p.W1207C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS18 | c.1859A>T p.K620M | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); called by muse, mutect2
- AHNAK2 | c.5307C>A p.D1769E | Missense Mutation (SNP) | VAF 37/548 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); called by muse, mutect2
- ALPK3 | c.3182C>T p.S1061F | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); called by muse, mutect2
- AP3B1 | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 43/385 reads (11%) | called by muse, mutect2, varscan2
- CDH18 | c.1154T>A p.M385K | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH6 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- CHL1 | c.904T>A p.Y302N (on ENST00000397491 / NM_001253387.1; = p.Y318N on NM_006614.4) | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2
- CNGA2 | c.1951G>T p.D651Y | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, varscan2
- COL6A6 | c.4454G>A p.G1485E | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.1005C>A p.Y335* | Nonsense Mutation (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- DDX3X | c.1077G>C p.Q359H (on ENST00000399959; = p.Q360H on NM_001356.5) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DLL3 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.557); called by muse, mutect2
- DNAH2 | c.2656C>A p.L886M | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2
- DOP1B | c.5666C>T p.S1889F | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); called by muse, mutect2
- DST | c.10365G>T p.L3455F | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.194); called by muse, mutect2
- ESPL1 | c.5350G>T p.D1784Y | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM181A | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2
- GLI3 | c.3886G>A p.G1296S | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2
- GLYAT | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); called by muse, mutect2
- GTF3A | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.644); called by muse, mutect2
- HEMGN | c.466C>A p.Q156K | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.66); called by muse, mutect2
- ICE1 | c.4213G>C p.V1405L | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- IGLV2-18 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 15/280 reads (5%) | called by muse, mutect2
- KATNIP | c.4551+1G>T p.X1517_splice | Splice Site (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- KAZN | c.1389G>A p.M463I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2
- KCNRG | c.655T>A p.L219I | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIAA2026 | c.3926G>A p.S1309N | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- KIZ | c.405+2dup p.X135_splice | Splice Site (INS) | VAF 9/78 reads (12%) | called by mutect2, varscan2
- KLHDC10 | c.1065G>C p.K355N | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); called by muse, mutect2
- KLHL1 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 10/285 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KMT2E | c.4624A>G p.T1542A | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- KNDC1 | c.3425A>T p.Y1142F | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- KRTAP9-9 | c.299G>C p.C100S | Missense Mutation (SNP) | VAF 38/548 reads (7%) | SIFT deleterious (0.01); called by muse, mutect2
- LILRB2 | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- LILRB3 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 18/475 reads (4%) | called by muse, mutect2
- LRRCC1 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2
- MDN1 | c.7642C>A p.Q2548K | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2
- MRPS5 | c.1278G>T p.K426N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.654); called by muse, mutect2
- MTMR4 | c.2725A>G p.S909G | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, mutect2
- MUC5AC | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT deleterious (0); called by muse, mutect2
- MYT1L | c.1274A>T p.D425V | Missense Mutation (SNP) | VAF 25/285 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NBPF10 | c.1969A>T p.R657* | Nonsense Mutation (SNP) | VAF 29/852 reads (3%) | called by muse, mutect2
- OR10V1 | c.481A>T p.T161S | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR5B12 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); called by muse, mutect2
- OTOGL | c.2124G>T p.K708N (on ENST00000547103; = p.K699N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/467 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2
- PARP12 | c.1320C>G p.F440L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); called by muse, mutect2
- PCDH11X | c.2757C>A p.Y919* | Nonsense Mutation (SNP) | VAF 23/259 reads (9%) | called by muse, mutect2
- PCDHA4 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHB4 | c.2023G>T p.A675S | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.097); called by muse, mutect2
- PCDHB8 | c.1325T>C p.V442A | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2
- PCDHGA3 | c.1621C>A p.P541T | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.513); called by muse, mutect2
- PLXNB3 | c.2382C>A p.D794E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- POLG2 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.046); called by muse, mutect2
- POT1 | c.386A>G p.D129G | Missense Mutation (SNP) | VAF 30/393 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- PRCC | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- PXDN | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RBM38 | c.106A>G p.I36V | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.13); called by muse, mutect2
- RIMS2 | c.1344G>C p.L448F (on ENST00000666250 / NM_001348490.2; = p.L256F on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.732); called by muse, mutect2
- SERPINB3 | c.1075A>T p.T359S | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC1A5 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.243); called by muse, mutect2
- SLC24A2 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SP9 | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ST18 | c.2332C>G p.H778D | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- THNSL1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEFF1 | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 13/186 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2
- TRIM29 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.443); called by muse, mutect2
- TTLL7 | c.1378C>A p.P460T | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.138); called by muse, mutect2
- USH2A | c.8882C>A p.T2961K | Missense Mutation (SNP) | VAF 39/360 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- USH2A | c.4403C>A p.A1468E | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.109); called by muse, mutect2
- VPS51 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.785); called by muse, mutect2
- XIRP1 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.198); called by muse, mutect2
- ZNF335 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF716 | c.879G>C p.E293D | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2
- ZNF728 | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2
- ZSWIM6 | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- ZSWIM6 | c.2523G>T p.M841I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- ATG14 | c.612C>G p.V204= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV99902574; called by muse, mutect2
- CCNA2 | c.1215A>T p.A405= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- CD19 | c.588C>A p.L196= | Silent (SNP) | VAF 15/339 reads (4%) | called by muse, mutect2
- CDON | c.297C>G p.A99= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- CEBPB | c.225C>T p.F75= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- ENOX1 | c.718C>A p.R240= | Silent (SNP) | VAF 14/247 reads (6%) | called by muse, mutect2
- GABRR1 | c.528C>A p.V176= | Silent (SNP) | VAF 28/382 reads (7%) | called by muse, mutect2
- GPRIN1 | c.2772A>G p.V924= | Silent (SNP) | VAF 13/138 reads (9%) | called by muse, mutect2, varscan2
- IFT43 | c.471C>T p.L157= (on ENST00000314067 / NM_001102564.3; = p.L162= on NM_052873.3) | Silent (SNP) | VAF 35/565 reads (6%) | catalogued as COSV99465921; called by muse, mutect2
- ITGB4 | c.105G>A p.V35= | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- KIF1B | c.1620C>T p.D540= (on ENST00000377086 / NM_001365952.1; = p.D494= on NM_015074.3) | Silent (SNP) | VAF 18/454 reads (4%) | called by muse, mutect2
- LAMA2 | c.5400T>A p.A1800= | Silent (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- MAN1B1 | c.1578G>T p.V526= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- MGAM | c.4407C>A p.I1469= | Silent (SNP) | VAF 20/436 reads (5%) | catalogued as COSV72073711; called by muse, mutect2
- MGAM2 | c.735T>G p.A245= | Silent (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- MYT1 | c.1185C>T p.V395= | Silent (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- PAOX | c.1017C>T p.I339= | Silent (SNP) | VAF 13/307 reads (4%) | catalogued as COSV53372947, COSV53374124; called by muse, mutect2
- PCDHA4 | c.900A>G p.G300= | Silent (SNP) | VAF 7/148 reads (5%) | catalogued as rs782664292, COSV63541859; called by muse, mutect2
- PLEKHH2 | c.1863A>C p.S621= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- PRMT7 | c.561C>T p.S187= | Silent (SNP) | VAF 20/233 reads (9%) | catalogued as rs781014616, COSV59832148; called by muse, mutect2
- RNASE3 | c.324C>A p.L108= | Silent (SNP) | VAF 30/486 reads (6%) | catalogued as rs1206424889, COSV58959541; called by muse, mutect2
- RYR3 | c.2547C>T p.F849= | Silent (SNP) | VAF 14/149 reads (9%) | catalogued as rs759679405; called by muse, mutect2
- SLC12A3 | c.472C>A p.R158= | Silent (SNP) | VAF 30/504 reads (6%) | catalogued as rs1041531529; called by muse, mutect2
- SLC4A3 | c.3549C>T p.F1183= | Silent (SNP) | VAF 15/208 reads (7%) | catalogued as rs1020179402; called by muse, mutect2
- SPEG | c.8142A>T p.R2714= | Silent (SNP) | VAF 7/131 reads (5%) | called by muse, mutect2
- TRIM77 | c.636C>T p.L212= | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- WDR87 | c.711C>A p.L237= | Silent (SNP) | VAF 16/303 reads (5%) | called by muse, mutect2
- WT1 | c.1098T>G p.L366= | Silent (SNP) | VAF 20/366 reads (5%) | catalogued as CD041625; called by muse, mutect2
- ZNF335 | c.717G>T p.V239= | Silent (SNP) | VAF 14/244 reads (6%) | called by muse, mutect2
- ABRAXAS1 | c.*1420G>A | 3'UTR (SNP) | VAF 6/93 reads (6%) | catalogued as rs1224244313; called by muse, mutect2
- AC006305.1 | n.1007C>G | RNA (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- AMER1 | c.*3731G>T | 3'UTR (SNP) | VAF 10/123 reads (8%) | catalogued as COSV57662169; called by muse, mutect2
- ANXA2P2 | n.507G>A | RNA (SNP) | VAF 21/442 reads (5%) | called by muse, mutect2
- ARHGAP27P2 | n.156T>A | RNA (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- BBS2 | c.1081-13G>C | Intron (SNP) | VAF 22/360 reads (6%) | catalogued as rs1485672088; called by muse, mutect2
- BIRC8 | n.1509C>A | RNA (SNP) | VAF 13/189 reads (7%) | called by muse, mutect2
- CDK10 | c.*11G>C | 3'UTR (SNP) | VAF 24/271 reads (9%) | called by muse, mutect2
- CPLANE1 | c.*2712T>C | 3'UTR (SNP) | VAF 25/382 reads (7%) | called by muse, mutect2
- FCRL4 | c.-6G>A | 5'UTR (SNP) | VAF 28/288 reads (10%) | called by muse, mutect2
- GABRD | c.471-9T>C | Intron (SNP) | VAF 28/494 reads (6%) | catalogued as rs752114528; called by muse, mutect2
- KREMEN2 | c.1178+35C>G | Intron (SNP) | VAF 8/99 reads (8%) | catalogued as COSV53555595; called by muse, mutect2
- MCF2L | c.369-539T>C | Intron (SNP) | VAF 27/552 reads (5%) | called by muse, mutect2
- OBSCN | c.11659+3549G>T | Intron (SNP) | VAF 26/327 reads (8%) | called by muse, mutect2
- OSGIN1 | n.1796G>T | RNA (SNP) | VAF 15/155 reads (10%) | called by muse, mutect2
- WDPCP | c.1748+8963G>C | Intron (SNP) | VAF 14/189 reads (7%) | called by muse, mutect2
